Gene-level copy-number profile of tumor specimen C3L-00445-01 from CPTAC case C3L-00445, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 74.8 years (27,320 days).
Specimen C3L-00445-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1aaa3fb7-26da-4a10-88e7-43070eb38c44.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00445-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,243 have no estimate.
https://portal.gdc.cancer.gov/files/818cd8d3-cb35-4bcc-a2cd-424bc56f43dd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 26,574; copy number 2: 28,801; copy number 3: 1,492; copy number 4: 1,426; copy number 5: 13; copy number 32: 17; copy number 41: 12; copy number 43: 22; copy number 46: 4.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,702,379–1,745,992, 4 genes (within-gene range 0–1): CDK11A, AL031282.2, AL031282.1, SLC35E2A.
- chr1:248,549,444–248,549,762, 1 gene (within-gene range 0–2): OR2AS1P.
- chr1:248,573,801–248,645,278, 6 genes: OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35.
- chr4:69,306,469–69,307,173, 1 gene (within-gene range 0–1): AC114786.3.
- chr5:71,032,670–71,133,287, 4 genes: GTF2H2, OCLNP1, NAIPP4, CDH12P4.
- chr8:12,378,679–12,400,366, 2 genes (within-gene range 0–1): AC087203.2, DEFB109A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 67 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:32,293,558–32,676,520, 12 genes, copy number 5: RNA5SP281, SLC25A5P8, ACO1, DDX58, TOPORS, SMIM27, NDUFB6, DFFBP1, TAF1L, AL589642.1, AL589642.2, SNRPCP1.
- chr13:112,602,828–114,337,626, 55 genes, copy number 32–46: AL139384.2, ATP11AUN, AL139384.1, ATP11A, ATP11A-AS1, AL356752.1, MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3, F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, RASA3, RASA3-IT1, CDC16, MIR548AR, MIR4502, UPF3A, CLCP2, CHAMP1, LINC01054.

Autosomal genes at a single copy (total copy number 1): 26,534. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
